Somatic mutation profile of tumor specimen ALCH-AEZL-TTP1-A (aliquot ALCH-AEZL-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.9 years (18,605 days).
Specimen ALCH-AEZL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76e2c8e8-dbb4-4324-85dd-56a4e905097c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEZL-NB1-A (Blood Derived Normal), aliquot ALCH-AEZL-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17445165-365a-40f7-ac11-f4177f3ca5e6

The open-access MAF lists 275 somatic variants for this specimen: 201 protein-altering or splice-affecting, 43 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 43, Intron 15, Nonsense Mutation 15, RNA 9, Splice Site 6, 3'UTR 5, Frame Shift Del 4, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 199/369 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.376-2A>T p.X126_splice | Splice Site (SNP) | VAF 86/221 reads (39%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.286G>A p.G96S (on ENST00000614293; = p.G66S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55799312; called by muse, mutect2, varscan2
- ACSM4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 11/249 reads (4%) | catalogued as COSV68066592; called by muse, mutect2
- ADGRG5 | c.935C>A p.S312* | Nonsense Mutation (SNP) | VAF 42/136 reads (31%) | catalogued as rs1359285592; called by muse, mutect2, varscan2
- ADGRL4 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1300143811; called by muse, mutect2
- ANKRD30B | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100744576; called by muse, mutect2, varscan2
- ARPP21 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141444314; called by muse, varscan2
- ATM | c.7967T>A p.L2656H | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM980154; called by muse, mutect2, varscan2
- BCAS4 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as rs1439440075; called by muse, varscan2
- CACNA2D1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); catalogued as COSV62395463; called by muse, mutect2, varscan2
- CCPG1 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs767211305, COSV60527477; called by muse, mutect2, varscan2
- CD22 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs200892922, COSV50060102; called by muse, mutect2, varscan2
- CHRNA2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199810678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMTR2 | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | catalogued as rs368654966; called by muse, mutect2, varscan2
- CPE | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV68580144; called by muse, mutect2, varscan2
- CPNE5 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as rs1438144376, COSV55198826; called by muse, mutect2, varscan2
- DGCR2 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV54218113; called by muse, mutect2, varscan2
- DNAH11 | c.11398G>C p.D3800H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs553943791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.7429G>T p.V2477L | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs765621822; called by muse, mutect2
- EBF4 | c.385G>A p.V129M (on ENST00000609451; = p.V125M on NM_001110514.1) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1393824526; called by muse, mutect2, varscan2
- FAM135B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs369404911, COSV50523175; called by muse, mutect2, varscan2
- FAM83B | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV60920772; called by muse, mutect2, varscan2
- FASTKD1 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as rs746061326; called by muse, mutect2, varscan2
- FAT3 | c.13325T>C p.L4442P | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.176); catalogued as COSV53081604; called by muse, mutect2
- FFAR3 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs1456734925; called by muse, mutect2, varscan2
- GPR83 | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99703724; called by muse, mutect2
- IFT46 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 97/406 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1555070257; called by muse, mutect2
- IGHV3-33 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as rs780190741; called by muse, mutect2, varscan2
- JAML | c.503T>C p.V168A (on ENST00000356289 / NM_001098526.2; = p.V158A on NM_153206.3) | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs1285735355; called by muse, varscan2
- KIRREL3 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs367826386, COSV101585701; called by muse, mutect2, varscan2
- KMT2D | c.3820G>C p.D1274H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV56436599; called by mutect2, varscan2
- LMX1B | c.1151G>A p.R384H (on ENST00000373474 / NM_001174147.2; = p.R377H on NM_002316.4) | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs143906016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRCH4 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761412341; called by mutect2, varscan2
- LRFN2 | c.2243T>C p.V748A | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs751826428; called by muse, mutect2, varscan2
- MALT1 | c.2011A>T p.R671* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | catalogued as COSV61936463; called by muse, mutect2, varscan2
- MAP4K5 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165816019; called by muse, mutect2, varscan2
- MARCHF11 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV60128582; called by muse, mutect2, varscan2
- MEF2C | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60934543; called by muse, mutect2, varscan2
- MGAM | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV71885978; called by muse, mutect2, varscan2
- MME | c.1861T>A p.C621S | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM164257; called by muse, mutect2, varscan2
- MS4A1 | c.780A>C p.E260D | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs201861406; called by muse, mutect2
- MUC6 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs762655679; called by muse, mutect2, varscan2
- MYO9B | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745558830; called by muse, mutect2, varscan2
- NLRP8 | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as COSV52588192; called by muse, mutect2, varscan2
- OR2T11 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV58185873; called by muse, mutect2
- PCGF3 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV62861133; called by muse, mutect2, varscan2
- PHIP | c.3811C>T p.L1271F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs373292877, COSV99243785; called by muse, mutect2, varscan2
- PLXNB2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as rs1333488993, COSV63780558; called by muse, mutect2, varscan2
- PMFBP1 | c.1919G>T p.G640V (on ENST00000537465; = p.G635V on NM_031293.3) | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52822696; called by muse, mutect2, varscan2
- POGK | c.604G>C p.A202P | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63311804; called by muse, mutect2
- PPIP5K2 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 30/222 reads (14%) | catalogued as COSV58607646; called by muse, mutect2, varscan2
- PPP1R3A | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 76/546 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs138953027; called by muse, mutect2, varscan2
- PRKN | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs747891099, HM070046, COSV58207384; called by muse, mutect2
- PTCHD3 | c.1691A>T p.K564M | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV71257311; called by muse, mutect2
- REV3L | c.2262A>C p.R754S | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs762336544; called by muse, mutect2, varscan2
- SPATA31A6 | c.3277T>C p.C1093R | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs755359656, COSV100253533; called by muse, mutect2, varscan2
- TBC1D5 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.822); catalogued as rs975008258; called by muse, mutect2, varscan2
- TES | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64041895; called by muse, mutect2, varscan2
- TNRC18 | c.1855A>G p.M619V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs758771635; called by muse, mutect2, varscan2
- USH2A | c.9264A>C p.E3088D | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100232289, COSV100232562, COSV100237869; called by muse, mutect2
- ZFP41 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV58086245; called by muse, mutect2, varscan2
- ZNF106 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55518683; called by muse, mutect2, varscan2
- ZNF536 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs764827458; called by mutect2, varscan2
- ZNF735 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); catalogued as rs954397858; called by muse, mutect2, varscan2
- ZNF837 | c.797del p.P266Rfs*141 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs1568565069, COSV69893051; called by pindel, varscan2
- ABI3BP | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAMTS13 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADAMTS14 | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1449A>C p.K483N | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADCY8 | c.3373G>T p.G1125W | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.157+1G>T p.X53_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- ADGRB3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AGBL4 | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.931); called by muse, mutect2
- ALDH3B1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ANKRD13D | c.*1103-3C>T | Splice Region (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- APC | c.2713A>C p.S905R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2
- ARID3C | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARMC4 | c.2033T>G p.L678R | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASB15 | c.964C>G p.Q322E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ATAD2B | c.2882G>C p.R961T | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- C5 | c.2685G>C p.L895F | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5orf51 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- C7orf31 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CADPS | c.2139C>A p.D713E | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CASD1 | c.1820T>G p.V607G | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC60 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD34 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CNR1 | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); called by muse, mutect2
- COBL | c.2321A>C p.N774T | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL25A1 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- COLCA2 | c.317G>C p.C106S | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- CPNE3 | c.528G>T p.M176I | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRIM1 | c.1067T>C p.F356S | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CSMD1 | c.8954C>A p.P2985H (on ENST00000520002; = p.P2984H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTSD | c.704+1G>T p.X235_splice | Splice Site (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNTTIP1 | c.106-2A>T p.X36_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- DOCK11 | c.3758del p.G1253Afs*31 | Frame Shift Del (DEL) | VAF 39/96 reads (41%) | called by mutect2, pindel, varscan2
- DSC3 | c.998T>G p.F333C | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- DYNC2H1 | c.5295G>T p.L1765F | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EHMT2 | c.3099G>C p.Q1033H | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ENPP4 | c.1074A>C p.K358N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2
- EVC2 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FASTKD1 | c.1907A>G p.N636S | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- FCRL2 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- FGD2 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, varscan2
- FRMD3 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FSIP2 | c.14114T>G p.V4705G | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- FSIP2 | c.20577A>C p.E6859D | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.78); called by muse, mutect2
- FUBP1 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GLIPR1L2 | c.551A>C p.H184P | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GOLGA8J | c.1210del p.E404Kfs*10 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by pindel*, varscan2
- GPR179 | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDC | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 57/432 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IDUA | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGBP1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IMMP2L | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2
- INPP5D | c.2860G>A p.G954R (on ENST00000445964 / NM_001017915.3; = p.G953R on NM_005541.5) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ITGA8 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- KEAP1 | c.842dup p.Q282Afs*68 | Frame Shift Ins (INS) | VAF 41/157 reads (26%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.5774T>C p.L1925P | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- KRTAP9-3 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- LAG3 | c.652del p.H218Ifs*4 | Frame Shift Del (DEL) | VAF 101/255 reads (40%) | called by mutect2, pindel, varscan2
- LHFPL2 | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- LRRC31 | c.439T>G p.L147V | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- MMP2 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MN1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- MTCL1 | c.1744G>T p.G582C (on ENST00000306329 / NM_001378206.1; = p.G222C on NM_015210.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTREX | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NEB | c.5506A>T p.S1836C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- NELFA | c.841G>C p.E281Q (on ENST00000542778; = p.E270Q on NM_005663.5) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2
- NEUROD6 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFX1 | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NPHS2 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NPY5R | c.1203G>T p.R401S | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- NRF1 | c.606+1G>T p.X202_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- NRSN1 | c.175T>G p.S59A | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- NXF1 | c.799-2A>T p.X267_splice | Splice Site (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- OCSTAMP | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OPCML | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR10G9 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- OR11H2 | c.851T>C p.M284T (on ENST00000556246; = p.M295T on NM_001197287.1) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by mutect2, varscan2
- OR2L5 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4K14 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OTOGL | c.4104C>A p.Y1368* (on ENST00000547103; = p.Y1359* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 94/157 reads (60%) | called by muse, mutect2, varscan2
- PCDH15 | c.5362C>T p.L1788F | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCDH17 | c.3411A>T p.E1137D | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PCDH9 | c.1475G>T p.S492I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB10 | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 54/351 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.6087T>G p.I2029M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2
- PDE1C | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PIK3R5 | c.341C>A p.T114N | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PKHD1 | c.9353G>T p.W3118L | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PKHD1L1 | c.10706C>A p.P3569Q | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.232); called by muse, mutect2
- PLCE1 | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- PLCH1 | c.2170G>T p.D724Y (on ENST00000340059 / NM_001130960.2; = p.D736Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PLXNA4 | c.3463C>G p.L1155V | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.457); called by muse, mutect2
- PPP3R2 | c.368A>C p.N123T | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PPP4R4 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRPSAP1 | c.647A>T p.Y216F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PXDN | c.3264C>G p.F1088L | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RIMS2 | c.2983C>T p.P995S (on ENST00000666250 / NM_001348490.2; = p.P803S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RSPO4 | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR3 | c.1604G>A p.C535Y | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN9A | c.4183G>T p.G1395C (on ENST00000303354; = p.G1384C on NM_002977.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDR16C5 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3A3 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHOX2 | c.650G>A p.C217Y (on ENST00000441443 / NM_006884.3; = p.C241Y on NM_003030.4) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIPA1L3 | c.1956G>T p.E652D | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SIRPA | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIRPD | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, varscan2
- SKAP1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLAMF9 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35A2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC35C2 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX17 | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GAL2 | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TBX18 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR2 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- TFRC | c.1753A>T p.K585* | Nonsense Mutation (SNP) | VAF 50/313 reads (16%) | called by muse, mutect2, varscan2
- THSD7B | c.166T>C p.C56R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPTE | c.829A>T p.N277Y (on ENST00000618007 / NM_199261.4; = p.N259Y on NM_199259.4) | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TRIM64 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TRIML1 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TUBA3C | c.559T>G p.S187A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ULK4 | c.3085A>C p.S1029R | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.216); called by muse, mutect2
- USP4 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- VPS39 | c.2627T>G p.F876C (on ENST00000348544 / NM_001301138.2; = p.F865C on NM_015289.5) | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VPS54 | c.627G>A p.L209= | Splice Region (SNP) | VAF 19/55 reads (35%) | called by muse, varscan2
- VWA5B1 | c.2951A>C p.K984T (on ENST00000375079; = p.K979T on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2
- ZBTB41 | c.1651A>T p.I551F | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ZEB1 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZNF155 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | called by muse, mutect2, varscan2
- ZNF648 | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZNF804A | c.1220T>G p.V407G | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZNF804A | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF804A | c.1792A>T p.K598* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1239A>T p.T413= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1845T>G p.A615= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- ALKAL1 | c.267A>G p.E89= | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1170T>C p.P390= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs770620343; called by muse, mutect2, varscan2
- APBB1IP | c.1926A>T p.G642= | Silent (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.183G>A p.T61= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- C4orf54 | c.94C>A p.R32= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV72766734; called by muse, mutect2, varscan2
- CELF3 | c.753C>A p.T251= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV51885316; called by muse, mutect2, varscan2
- CELSR3 | c.2094T>A p.P698= | Silent (SNP) | VAF 33/197 reads (17%) | called by muse, mutect2, varscan2
- CUBN | c.5136G>T p.L1712= | Silent (SNP) | VAF 86/322 reads (27%) | called by muse, mutect2, varscan2
- EXD3 | c.678C>T p.S226= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- FAT3 | c.7989G>A p.K2663= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV53079327; called by muse, mutect2, varscan2
- FMO2 | c.351A>G p.P117= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs926555294; called by muse, mutect2
- GLI4 | c.474G>T p.A158= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- HOXA1 | c.516C>G p.A172= | Silent (SNP) | VAF 60/224 reads (27%) | called by muse, varscan2
- IRGQ | c.1356A>T p.P452= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- LRIG3 | c.3036T>C p.N1012= | Silent (SNP) | VAF 35/238 reads (15%) | catalogued as rs777613135; called by muse, mutect2, varscan2
- LZTS1 | c.93C>T p.L31= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- MED1 | c.4182C>T p.I1394= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV56127614; called by muse, mutect2, varscan2
- MED17 | c.39G>A p.S13= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- NLRP11 | c.756A>G p.K252= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs769134961; called by muse, mutect2, varscan2
- NTNG1 | c.1569G>C p.A523= (on ENST00000370068 / NM_001113226.3; = p.A422= on NM_014917.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100903743; called by muse, mutect2, varscan2
- OR10G8 | c.675G>T p.L225= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- OR14C36 | c.729C>A p.I243= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV58602721; called by muse, mutect2, varscan2
- PCDHB13 | c.2253T>C p.Y751= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- PDGFRL | c.459C>T p.C153= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- PKHD1 | c.9123T>C p.N3041= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- POU4F2 | c.330C>A p.R110= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- SAXO2 | c.501A>C p.P167= | Silent (SNP) | VAF 43/260 reads (17%) | called by muse, mutect2, varscan2
- SCAF11 | c.2226A>G p.K742= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- SF3A3 | c.777T>A p.G259= | Silent (SNP) | VAF 36/202 reads (18%) | called by muse, varscan2
- SLC7A9 | c.1236C>T p.V412= | Silent (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- SLC9A4 | c.1767G>T p.V589= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, varscan2
- SMARCA2 | c.2316C>T p.L772= | Silent (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.4503A>G p.K1501= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.2493G>A p.L831= | Silent (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- TRPM5 | c.2646G>A p.V882= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- UBASH3B | c.672A>G p.L224= | Silent (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- UGT1A10 | c.93G>T p.V31= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as rs144511743; called by muse, mutect2, varscan2
- YY2 | c.942A>T p.T314= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- ZBTB33 | c.1863T>C p.T621= | Silent (SNP) | VAF 82/152 reads (54%) | called by muse, mutect2, varscan2
- ZNF181 | c.126T>C p.S42= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs1459184981; called by muse, mutect2, varscan2
- ZNF311 | c.1242T>G p.P414= | Silent (SNP) | VAF 39/335 reads (12%) | called by muse, mutect2, varscan2
- AC241585.2 | n.533G>T | RNA (SNP) | VAF 9/67 reads (13%) | called by mutect2, varscan2
- ADAM8 | c.705+10G>T | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- AMFR | c.*593G>T | 3'UTR (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- BRCA1 | c.4358-2782C>T | Intron (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- CCNT2 | c.494-225G>T | Intron (SNP) | VAF 33/217 reads (15%) | called by muse, mutect2, varscan2
- DCD | c.98-341C>A | Intron (SNP) | VAF 126/241 reads (52%) | called by muse, mutect2, varscan2
- DCHS2 | n.6886C>A | RNA (SNP) | VAF 97/292 reads (33%) | catalogued as rs1425943014, COSV61769283, COSV61769838; called by muse, mutect2, varscan2
- DCHS2 | n.780C>A | RNA (SNP) | VAF 86/192 reads (45%) | called by muse, mutect2, varscan2
- FAM74A7 | n.667A>G | RNA (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2, varscan2
- FCRL3 | c.*1965A>G | 3'UTR (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- FCRL4 | c.1250-25A>C | Intron (SNP) | VAF 22/218 reads (10%) | catalogued as COSV99619917; called by muse, mutect2, varscan2
- GPM6B | c.61+9181C>T | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- KRT8P11 | n.691A>C | RNA (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- LGALS13 | c.-11del | 5'UTR (DEL) | VAF 128/355 reads (36%) | called by mutect2, pindel, varscan2
- LINC02691 | n.1349G>A | RNA (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- MS4A6E | c.147+501A>G | Intron (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- NANOGNB | c.*51G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | catalogued as rs1293229165; called by muse, mutect2, varscan2
- NHLRC2 | c.*6608G>T | 3'UTR (SNP) | VAF 18/288 reads (6%) | catalogued as rs778332141; called by muse, mutect2
- NOP2 | c.1790-474C>T | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.2746-392C>T | Intron (SNP) | VAF 43/170 reads (25%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6311A>G | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- RFX4 | c.378-2042A>G | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- SEC16B | c.1775+46del | Intron (DEL) | VAF 40/201 reads (20%) | called by mutect2, pindel, varscan2
- SNORD109A | n.43C>A | RNA (SNP) | VAF 22/136 reads (16%) | called by muse, varscan2
- TGFBR3 | c.*2568C>G | 3'UTR (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- TMC2 | c.1872+63T>C | Intron (SNP) | VAF 66/207 reads (32%) | catalogued as rs983543837; called by muse, mutect2, varscan2
- TPRXL | n.567G>T | RNA (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- TPRXL | n.568G>T | RNA (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- VSIG10L2 | chr11:125942957 G>T | 5'Flank (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- WIPI2 | c.212-165C>T | Intron (SNP) | VAF 14/46 reads (30%) | called by muse, varscan2
- ZNF497 | c.-111-956A>T | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
